Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3358, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3358-01A (Primary Tumor).

[page 1 of 2]
TEST: Surgical PathologyCollected Date & Time: [REDACTED]

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Left renal mass

Post-Op Diagnosis

Same as above

Clinical History

Same as above

Gross Description:

Received in a single container labeled [REDACTED] - left kidney" is a 980 gram previously partially bisected left nephrectomy specimen surrounded by a large amount of perinephric adipose tissue enfaced anteriorly by a moderate amount of Gerota's fascia. The specimen as received on reconstruction measures 26.7 x 11.8 x 8.7 cm. Noted in the superior antral medial aspect of the perinephric adipose tissue is a 5.9 x 3.0 x 1.3 cm adrenal gland. The renal margins of resection include 1.3 cm of grossly patent renal artery, 0.5 cm of grossly patent renal vein, and 9.8 cm of grossly patent ureter. The capsule strips with ease to reveal an organ measuring 11.4 x 7.2 x 5.6 cm. This has a lobulated finely granular red brown cortical surface. The specimen is previously sectioned in the low posterior pole to reveal an eccentric 2.7 x 2.5 x 2.2 cm well circumscribed thinly encapsulated chalky gray yellow to brown focally hemorrhagic lesion. On sectioning this lesion has a tan pink to yellow focally hemorrhagic cut surface but appears grossly confined to the capsule. This grossly appears to focally extend to within 0.1 cm of the cortical margin; however, the lesion does not appear to extend beyond the capsule into the cortex. The surrounding parenchyma is slightly focally compressed by this lesion; however, the lesion does not grossly appear to extend into the parenchyma. The remaining renal parenchyma consists of a cortex measuring up to 0.9 cm which is slightly granular homogenous red brown. The cortical medullary junction is poorly defined. The medulla is red brown with sharp papillae. The calices and pelvis are lined by smooth tan white mucosa which extends into the ureter.

Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - vascular and ureteral margins, B through E - representative lesion and surrounding tissue, F - random uninvolved parenchyma, G - representative adrenal gland.

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final DiagnosisLeft kidney:Tumor characteristics:

1. Histologic type: Renal cell carcinoma, clear cell type.
2. Tumor site: Lower pole.
3. Size: 2.7 cm in greatest diameter.
4. Macroscopic extent of tumor: Tumor limited to kidney.
5. Nuclear grade: 1-2/4
6. Lymphovascular space invasion: Focal tumor identified within endothelial-lined lymphovascular space.

7. Transcapsular invasion: No.
8. Renal vein invasion: No.
9. Vena caval invasion: Not resected.

Surgical margin status:

1. Soft tissue margins: Negative.

[page 2 of 2]
2. Ureteral margin: Negative.

3. Vascular margin: Negative.

Lymph node status:

No lymph nodes resected.

Other:

Left adrenal gland: No pathologic diagnosis. PAS 9 SPC-A

CPT: 88307 x 2

Comments

This test has been finalized at the [REDACTED] Campus.

#

[REDACTED]

Viewed By

Date & Time

Source: NCI Genomic Data Commons file eddd7fcc-ac82-48e0-8471-9278702c5776 (TCGA-A3-3358.75630D62-03F2-4E5F-B7D4-EA7885073D6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).